Somatic mutation profile of tumor specimen MMRF_1833_1_BM_CD138pos (aliquot MMRF_1833_1_BM_CD138pos_T1_KBS5U_L05813) from MMRF case MMRF_1833, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.0 years (22,279 days).
Specimen MMRF_1833_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2680fa40-1adf-47cd-8f3b-a4fb21a39041.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1833_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1833_1_PB_Whole_C3_KBS5U_L05819; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93367558-b1d9-41d1-8461-d16e0917210a

The open-access MAF lists 131 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 42, Intron 16, Silent 14, RNA 4, Nonsense Mutation 4, 5'Flank 3, 5'UTR 2, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCDC18 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs559419360, CM125198; called by muse, mutect2, varscan2
- CCDC88C | c.3763C>T p.R1255W | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs1226329586, COSV66240592; called by muse, mutect2, varscan2
- CCN5 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.748); catalogued as COSV51935987, COSV51937525; called by muse, mutect2, varscan2
- CSMD3 | c.8598G>T p.Q2866H (on ENST00000297405 / NM_001363185.1; = p.Q2697H on NM_052900.3) | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs1217069033; called by muse, mutect2, varscan2
- CTNND1 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771907778; called by muse, mutect2, varscan2
- DIS3 | c.1436A>C p.D479A | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705800, COSV66705888; called by muse, mutect2, varscan2
- EVA1B | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.023); catalogued as rs967971768; called by muse, mutect2, varscan2
- FN1 | c.5854C>T p.R1952C | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs781268073, COSV60552523; called by muse, mutect2, varscan2
- HAS1 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.01); catalogued as rs975764736; called by muse, mutect2, varscan2
- IGHV3-30 | c.118T>G p.S40A | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as rs779400158; called by muse, varscan2
- IGHV3-30 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 49/212 reads (23%) | catalogued as rs1170624423; called by muse, varscan2
- IGLV3-1 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.662); catalogued as rs189772470; called by muse, varscan2
- KDM3B | c.4205G>A p.W1402* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV100070427; called by muse, mutect2, varscan2
- KLHDC8B | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776378063; called by muse, mutect2, varscan2
- LENG8 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs141114315; called by muse, mutect2, varscan2
- MISP | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs776345030, COSV53119908; called by muse, mutect2, varscan2
- ROBO1 | c.643G>C p.D215H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71392911; called by muse, mutect2, varscan2
- SALL3 | c.3439G>A p.G1147S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1455914542; called by muse, mutect2, varscan2
- SPPL2C | c.643del p.R215Gfs*41 | Frame Shift Del (DEL) | VAF 61/114 reads (54%) | catalogued as COSV61292478; called by mutect2, pindel, varscan2
- TTN | c.84848C>T p.S28283L (on ENST00000591111; = p.S20859L on NM_003319.4) | Missense Mutation (SNP) | VAF 57/165 reads (35%) | PolyPhen benign (0.047); catalogued as rs1391021761; called by muse, mutect2, varscan2
- TUBA3C | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.104); catalogued as rs748945233, COSV67139000, COSV67139414; called by muse, mutect2, varscan2
- UTP20 | c.3637G>T p.A1213S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV104376618; called by muse, mutect2, varscan2
- ABCA4 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALKBH1 | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANAPC1 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CA3 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CTSO | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DAPP1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- DENND2C | c.1169A>G p.E390G | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPN3 | c.249C>G p.Y83* | Nonsense Mutation (SNP) | VAF 87/274 reads (32%) | called by muse, mutect2, varscan2
- FBN3 | c.4555T>C p.C1519R | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMN2 | c.4438A>C p.T1480P | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, varscan2
- GPR155 | c.1882C>T p.H628Y | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, varscan2
- HMCN1 | c.16723G>A p.E5575K | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- IGKV2-30 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LFNG | c.126_129dup p.R44Gfs*14 | Frame Shift Ins (INS) | VAF 22/72 reads (31%) | called by mutect2, varscan2
- LRP1B | c.9646G>A p.G3216R | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PKHD1 | c.1547T>A p.L516H | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- POU2F3 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- PRH1 | c.332A>T p.K111M | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); called by muse, varscan2
- RRAS | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2
- SHOC2 | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- SLC6A16 | c.1994C>T p.T665I | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLFN12 | c.1308G>C p.E436D | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2
- SMCP | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 15/400 reads (4%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.745); called by muse, mutect2
- TENM2 | c.5732A>T p.E1911V (on ENST00000518659 / NM_001122679.2; = p.E1672V on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TRAF3 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- UCP2 | c.187A>C p.M63L | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARD10 | c.459G>C p.R153= | Silent (SNP) | VAF 16/27 reads (59%) | called by muse, mutect2, varscan2
- CATSPERG | c.1701G>A p.Q567= | Silent (SNP) | VAF 19/228 reads (8%) | called by muse, mutect2
- CHD1 | c.993T>C p.T331= | Silent (SNP) | VAF 52/130 reads (40%) | called by muse, mutect2, varscan2
- CSHL1 | c.114G>A p.E38= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs201066747; called by muse, mutect2, varscan2
- HELZ2 | c.657C>G p.L219= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs771092012; called by muse, mutect2, varscan2
- MTA3 | c.687C>A p.S229= | Silent (SNP) | VAF 8/123 reads (7%) | called by muse, mutect2
- MUC16 | c.17061T>A p.P5687= | Silent (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- MXRA5 | c.417C>A p.I139= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- OPRM1 | c.252G>A p.G84= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV57681265; called by muse, varscan2
- PPAN-P2RY11 | c.1653C>T p.I551= | Silent (SNP) | VAF 117/468 reads (25%) | catalogued as rs374527129; called by muse, mutect2, varscan2
- SEMA5B | c.3096C>T p.F1032= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- TANC2 | c.558A>T p.T186= | Silent (SNP) | VAF 14/135 reads (10%) | catalogued as COSV101267420; called by muse, mutect2
- TMEM250 | c.237A>G p.L79= | Silent (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- TUBG2 | c.81C>T p.A27= | Silent (SNP) | VAF 57/126 reads (45%) | called by muse, mutect2, varscan2
- AAAS | c.400-89G>T | Intron (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- ADAM23 | c.*2063G>T | 3'UTR (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.*737dup | 3'UTR (INS) | VAF 36/140 reads (26%) | called by mutect2, varscan2
- BCL7A | chr12:122021103 T>A | 5'Flank (SNP) | VAF 28/75 reads (37%) | catalogued as COSV55851754; called by muse, mutect2, varscan2
- C7orf65 | n.1475G>A | RNA (SNP) | VAF 54/152 reads (36%) | called by muse, mutect2, varscan2
- C8orf37 | c.*1005C>G | 3'UTR (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- CACNB4 | c.*6337A>G | 3'UTR (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- CAMK4 | c.*4794G>A | 3'UTR (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2
- CCDC57 | c.2241+3409T>C | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- CDCA7 | c.*392C>T | 3'UTR (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- CDK2AP2 | c.82+78A>G | Intron (SNP) | VAF 31/224 reads (14%) | called by muse, mutect2, varscan2
- CFAP300 | c.675+144G>A | Intron (SNP) | VAF 74/227 reads (33%) | called by muse, mutect2, varscan2
- CHRM3 | c.*2065A>T | 3'UTR (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- CRTAP | c.*1037C>T | 3'UTR (SNP) | VAF 11/78 reads (14%) | catalogued as rs933175844; called by muse, mutect2, varscan2
- DCTN5 | c.*191C>T | 3'UTR (SNP) | VAF 22/36 reads (61%) | called by muse, mutect2, varscan2
- DEPDC4 | c.879-1095G>T | Intron (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- DHRS1 | c.507+83C>T | Intron (SNP) | VAF 19/28 reads (68%) | called by muse, mutect2, varscan2
- DISC1 | c.1793-11A>G | Intron (SNP) | VAF 11/33 reads (33%) | catalogued as rs1246246147; called by muse, varscan2
- DMBX1 | c.*1062C>G | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- DNAJB4 | c.*896A>C | 3'UTR (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- DPY19L2 | c.*556T>A | 3'UTR (SNP) | VAF 38/195 reads (19%) | catalogued as rs535202617; called by mutect2, varscan2
- EHD3 | c.*1730G>T | 3'UTR (SNP) | VAF 17/47 reads (36%) | catalogued as rs1285305084; called by muse, mutect2, varscan2
- ENTPD2 | c.1150-283C>A | Intron (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- EPHA5 | c.*4230T>A | 3'UTR (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- EVA1A | c.*271C>T | 3'UTR (SNP) | VAF 10/43 reads (23%) | catalogued as rs941499348; called by muse, varscan2
- EYS | c.1766+4507A>C | Intron (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- FAM114A2 | c.*657C>G | 3'UTR (SNP) | VAF 42/67 reads (63%) | catalogued as rs1273375846; called by muse, mutect2, varscan2
- HERC4 | c.387-1717A>G | Intron (SNP) | VAF 8/49 reads (16%) | catalogued as rs974199491; called by muse, mutect2, varscan2
- HOXB8 | c.*751dup | 3'UTR (INS) | VAF 8/28 reads (29%) | catalogued as rs1355261591; called by mutect2, varscan2
- INSL4 | c.*1218A>G | 3'UTR (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- KCNV1 | c.-291G>A | 5'UTR (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- KLF3 | c.*1914T>A | 3'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- KMT2B | c.7551-71G>A | Intron (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- LINC01549 | n.223C>G | RNA (SNP) | VAF 83/260 reads (32%) | called by muse, mutect2, varscan2
- LMCD1 | chr3:8501654 C>A | 5'Flank (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- LRRC20 | c.*371A>G | 3'UTR (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- LTB | c.162+178C>T | Intron (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- MAN2B1 | c.436+39C>T | Intron (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- MIR3679 | n.11A>T | RNA (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- NBPF22P | n.1094C>A | RNA (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- NCAM2 | c.*2948T>G | 3'UTR (SNP) | VAF 39/59 reads (66%) | called by muse, mutect2, varscan2
- NCOR1 | c.*408G>C | 3'UTR (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- NKAIN3 | c.472-55069T>C | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- OXSR1 | c.*1441C>G | 3'UTR (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- PATJ | c.*1357C>T | 3'UTR (SNP) | VAF 70/221 reads (32%) | called by muse, mutect2, varscan2
- PDE4A | c.-152C>T | 5'UTR (SNP) | VAF 5/11 reads (45%) | catalogued as rs1158126477; called by muse, mutect2, varscan2
- QPCTL | chr19:45692579 C>A | 5'Flank (SNP) | VAF 18/39 reads (46%) | called by mutect2, varscan2
- QRSL1 | c.*1839C>T | 3'UTR (SNP) | VAF 35/80 reads (44%) | catalogued as rs972172613; called by muse, mutect2, varscan2
- ROM1 | c.*210T>C | 3'UTR (SNP) | VAF 30/115 reads (26%) | called by muse, mutect2, varscan2
- SMOC2 | c.*1408T>G | 3'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- SPINK5 | c.411-61G>A | Intron (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- ST3GAL5 | c.319-4987G>A | Intron (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- STRN | c.*3415T>A | 3'UTR (SNP) | VAF 4/41 reads (10%) | catalogued as rs1051480181, COSV55753357; called by muse, mutect2
- TANC1 | c.*106dup | 3'UTR (INS) | VAF 20/54 reads (37%) | catalogued as rs940158200; called by mutect2, varscan2
- TDRD9 | c.*458A>T | 3'UTR (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- TECPR2 | c.*1948G>C | 3'UTR (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- TECPR2 | c.*2367G>T | 3'UTR (SNP) | VAF 14/60 reads (23%) | called by muse, varscan2
- TECPR2 | c.*2503G>C | 3'UTR (SNP) | VAF 7/18 reads (39%) | called by muse, varscan2
- TECPR2 | c.*2554G>T | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- TECPR2 | c.*2622G>T | 3'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- TECPR2 | c.*2892G>C | 3'UTR (SNP) | VAF 6/60 reads (10%) | catalogued as rs1407081420; called by muse, mutect2
- TECPR2 | c.*3038G>T | 3'UTR (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- TECPR2 | c.*4158G>C | 3'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- TPSD1 | chr16:1262877 G>T | 3'Flank (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- WDR37 | c.*509C>T | 3'UTR (SNP) | VAF 24/43 reads (56%) | called by muse, mutect2, varscan2
- ZNF425 | c.*188G>A | 3'UTR (SNP) | VAF 19/100 reads (19%) | called by muse, mutect2, varscan2
- ZNF514 | c.*36C>T | 3'UTR (SNP) | VAF 66/225 reads (29%) | called by muse, mutect2, varscan2
- ZNF527 | c.*1096A>G | 3'UTR (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
